Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5326, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5326-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Neck: Contents right neck, left neck, mandibulectomy, intra oral resection right floor of mouth
2. Neck: Left level 2 neck dissection
3. Oral Cavity: Soft palate margin/QS
4. Oral Cavity: Deep margin/QS
5. Oral Cavity: Tongue margin/QS ..
6. Surgical Waste

Diagnosis

1. Oral cavity; contents right neck, left neck, mandibulectomy, and intra-oral resection right floor of mouth.
Squamous cell carcinoma, poorly differentiated.
- a. The tumor involves mandible, floor of mouth, right sublingual gland, and soft tissues of level I.
- b. Tumor maximum diameter 7.0 cm.
- c. Perineural invasion is present.
- d. No lymphatic/vascular invasion.
- e. Margins of resection negative for tumor. The tumor is close to lateral and medial (0.1 and 0.2 cm) soft tissue margins of the neck, and soft tissue margins of floor of mouth (0.3 cm).
- f. Decalcified sections of the mandible are pending. An addendum report will follow.
- g. Metastatic squamous cell carcinoma involving eighteen of thirty-four right neck lymph nodes (18/34).
- i. The largest lymph node involved measures 5.0 cm.
- ii. Extensive extranodal invasion is present.
- iii. The lymph nodes involved are in levels II-V.
- h. Metastatic squamous cell carcinoma involving one of twenty-one left neck lymph nodes (1/21).
- i. The largest lymph node involved measures 1.7 cm.
- ii. No extranodal invasion is present.
- iii. The lymph node involved is in level IV.
2. Left level II neck dissection.
One lymph node negative for tumor (0/1).
3. Soft palate margin.
Squamous mucosa negative for tumor.
4. Deep margin.
Minor salivary glands and soft tissues negative for tumor.
5. Tongue margin.
Squamous mucosa negative for tumor.

[page 2 of 4]
Surgical Pathology Consultation Report

6. Surgical waste.

Fragments of skin, bone, and soft tissues with no pathologic changes. (Gross examination only)

Synoptic Data

Specimen Type:	Resection: contents right neck, left neck, mandibulectomy, and intra-oral resection right floor of mouth.
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 7.0 cm
Histologic Grade:	G3: Poorly differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Present
Margins:	Margins uninvolved by tumor Margins uninvolved by tumor - Distance of tumor from closest margin: 0.1 cm Margins: The tumor is close to lateral and medial (0.1 and 0.2 cm) soft tissue margins of the neck, and soft tissue margins of floor of mouth (0.3 cm).
Pathologic Staging (pTNM):	pT4a: Oral cavity: Tumor invades adjacent structures (eg, through cortical bone, into deep [extrinsic] muscle of tongue [genioglossus, hyoglossus, palatoglossus, and styloglossus], maxillary sinus, skin of face) pN2c: Metastasis in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx Number of regional lymph nodes examined: 56 Number of regional lymph nodes involved: 19 Extra-capsular extension of nodal tumor: Present pMX: Distant metastasis cannot be assessed

Clinical History

oral ca

Gross Description

1. The specimen is labeled with the patient's name and NCK: Contents right neck, left neck, mandibulectomy, intraoral resection right floor of mouth". It consists of a segment of mandible, with attached floor of mouth and bilateral neck dissections with overall measurements of 11.0 cm AP x 22.5 SI x 10.0 ML cm. The portion of right mandible measures 6.0 cm AP x 2.5 cm SI x 3.0 cm ML. The lower alveolar ridge is edentulous. There is a tumor arising in the alveolar ridge. The tumor measures 5.5 AP x 7.0 SI x 4.7 ML cm. The tumor appears ulcerated and involves mandibular bone, floor of mouth and the adjacent right neck dissection, where it forms a large, partially necrotic mass, substantially replacing the right level I with extension into level II. The tumor involves the right parotid and right submandibular glands. The tumor is located at 0.1 cm from the closest right lateral soft tissue margin. The distance from the remaining margins to the tumor are as follows: anterior alveolar mucosa 1.0 cm, posterior alveolar mucosa 1.8 cm, right lateral alveolar mucosa 0.4 cm, anterior floor of mouth mucosa 0.8 cm, posterior floor of mouth mucosa 0.5 cm, medial floor of mouth mucosa 0.6 cm, right anterior soft tissue 1.3 cm, right posterior soft tissue 0.8 cm, medial soft tissue 0.2 cm and inferior to floor of mouth soft tissue 0.3 cm. The right neck dissection measures 9.0 cm AP by 15.3 cm SI by 5.5 cm ML and includes levels I, II, III, IV and V. The right submandibular gland measures 4.2 x 2.5 x 2.0 cm and is grossly involved by tumor. The right sternocleidomastoid muscle measures 10.3 x 4.0 x 2.8 cm and is adjacent to, but not grossly involved by tumor. The left neck dissection measures 5.5 cm AP by 17.3 cm SI by 2.5 cm ML and includes levels I, II, III and IV. The left submandibular gland measures 3.8 x 2.7 x 1.8 cm and is grossly unremarkable. The left sternocleidomastoid muscle is absent. Multiple lymph nodes are present in all levels, measuring from 0.2 to 5.0 cm in maximum dimension. Several

[page 3 of 4]
Surgical Pathology Consultation Report

large nodes within right levels II and III are obviously involved by tumor. Multiple pieces of tumor and normal tissue are taken for the tissue bank. Representative sections are submitted.

- 1A right anterior alveolar ridge mucosal margin, margin marked with India ink
- 1B right posterior alveolar ridge mucosal margin with tumor
- 1C right lateral alveolar ridge mucosal margin with tumor
- 1D right anterior floor of mouth mucosal margin with tumor
- 1E right posterior floor of mouth mucosal margin with tumor
- 1F right medial floor of mouth mucosal margin with tumor
- 1G right anterior soft tissue margin with tumor
- 1H right posterior soft tissue margin with tumor
- 1I medial soft tissue margin with tumor
- 1J right lateral soft tissue margin with tumor
- 1K inferior to floor of mouth soft tissue margin with tumor
- 1L right parotid gland involved by tumor
- 1M right submandibular gland involved by tumor
- 1N-1O right sternocleidomastoid muscle with adjacent tumor
- 1P-1Q right level II lymph nodes grossly involved by tumor, one representative section per node per block
- 1R right level II, three lymph nodes
- 1S-1T right level III lymph nodes grossly involved by tumor, one representative section per node per block
- 1U-1V right level III, one lymph node per block
- 1W right level III, two lymph nodes
- 1X right level III, three lymph nodes
- 1Y right level IV, one lymph node
- 1Z-1AA right level IV, three lymph nodes per block
- 1AB right level V, one lymph node
- 1AC-1AD right level V, one lymph node per block
- 1AE-1AG right level V, two lymph nodes per block
- 1AH right level V, three lymph nodes
- 1AI left submandibular gland
- 1AJ left level I, one lymph node
- 1AK left level I, one lymph node
- 1AL-1AN left level II, two lymph nodes per block
- 1AO-1AP left level III, one lymph node per block
- 1AQ left level III, three lymph nodes
- 1AR left level III, four lymph nodes
- 1AS left level IV, one lymph node
- 1AT-1AV left level IV, two lymph nodes per block
- 1AW-1AX anterior mandible margin en face, bisected superior-inferior, decalcified
- 1AY-1AZ posterior mandible margin en face, bisected superior-inferior, decalcified
- 1BA-1BB each block containing a full thickness section of mandible, with mass, decalcified

2. The specimen is labeled with the patient's name and "neck: Left level 2 neck dissection". It consists of two irregular pieces of soft tissue measuring 0.6 x 0.2 x 0.2 and 0.8 x 0.6 x 0.3 cm.

2A specimen in toto

3. The specimen is labeled with the patient's name and "Oral cavity: Soft palate margin/QS". It consists of a fragment of tissue measuring 1.2 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

2A frozen section control

4. The specimen is labeled with the patient's name and "Oral cavity: Deep margin/QS". It consists of a fragment of tissue measuring 0.4 x 0.4 x 0.4 cm. The specimen is submitted in toto for frozen section.

4A frozen section control

5. The specimen is labeled with the patient's name and "Oral cavity: Tongue margin/QS". It consists of a fragment of tissue measuring 1.4 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

5A frozen section control

6. The specimen is labeled with the patient's name and "surgical waste". It consists of an 8.2 x 8.0 x 2.8 cm aggregate of unremarkable bone, skin and soft tissue pieces. No sections for microscopic are submitted.

[page 4 of 4]
[REDACTED] Surgical Pathology Consultation Report [REDACTED]

[REDACTED]
Quick Section Diagnosis

3-5: Margins (soft palate, deep, tongue): Negative for malignancy. [REDACTED]

Addendum

Addendum Comment

Decalcified sections shows extensive invasion of the mandible by squamous cell carcinoma. The bone margins of resection are negative for carcinoma.

Source: NCI Genomic Data Commons file 801c5803-c94a-482c-9356-37f4dc139354 (TCGA-CQ-5326.5EDEC7EE-0A8D-40A7-A1DB-8E6BF848E1CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).